CCDI case PBBMVW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Eye and adnexa.
https://portal.gdc.cancer.gov/cases/43b3f5be-43c2-46c8-85be-739163bde349

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Spindle cell rhabdomyosarcoma: ICD-O-3 morphology code: 8912/3; Tissue or organ of origin: Orbit, NOS; Age at diagnosis: 7.5 years (2,754 days).

Biospecimens (3 samples)
- Sample 0DCX8Y: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCX9O: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCXB6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
